Surgical pathology report (de-identified scan), TCGA case TCGA-WB-A81I, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Erasmus MC, specimen TCGA-WB-A81I-01A (Primary Tumor).

Unique Patient Identifier:

Short descriptive translation of the pathology review reported by the

Pathoanatomical review

Date:

Date report:

Material: right adrenal

Grossly, there is a red and light tan tumor with a diameter of 2.1 cm. Histologically, the tumor was composed of pleomorph medium sized cells with slightly enlarged nuclei, chromatin and prominent nucleoli. Single cells display more pronounced pleomorphy and more enlarged nuclei. The tumor is well separated from adjacent tissue, partly by a fibrous capsule. Single cells have hyaline globules. No significant increase in the number of mitoses, no evidence for necrosis, vessel invasion or capsule destruction.

PASS-Score:

Large cell nests

(in > 10 %

(2) 0

Necrosis

(2) 0

Increased cellularity

(2) 0

Cellular monotony

(2) 0

Tumor cell spindling

(2) 0

Mitotic figures

(> 3/10 HPF) (2) 0

Extension into adipose tissue

(2) 0

Vascular invasion

(1) 0

Capsular invasion

(1) 0

Profound nuclear pleomorphism

(1) 1

Nuclear Hyperchromasia

(1) 0

Total Score Score (max. 20) 1

Final diagnosis: pheochromocytoma

Translated by:

ICD-O-3
Pheochromocytoma NOS
8100/0
Site R Adrenal gland
C74.9
9/10/17/13

MRSA Discrepancy		☒

Source: NCI Genomic Data Commons file 6d7d061a-01fe-492c-aaec-49a6ba191ccf (TCGA-WB-A81I.4DCB1F0F-9C53-423A-B4B1-BA5CC1BBCAC6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).